Somatic mutation profile of tumor specimen TCGA-AA-3673-01A (aliquot TCGA-AA-3673-01A-01W-0900-09) from TCGA case TCGA-AA-3673, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage II; Age at diagnosis: 53.4 years (19,509 days).
Specimen TCGA-AA-3673-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03af86f0-2fd1-44cf-bc3a-ae8f36887880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3673-10A (Blood Derived Normal), aliquot TCGA-AA-3673-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b468ea1c-72ad-4f87-844c-9e8d30526106

The open-access MAF lists 80 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 15, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, RNA 3, 5'UTR 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 48/112 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 63/125 reads (50%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM29 | c.2065A>G p.I689V | Missense Mutation (SNP) | VAF 153/384 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV63668598; called by muse, mutect2, varscan2
- AFAP1L2 | c.1127G>C p.R376T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100412648, COSV58418840; called by muse, mutect2, varscan2
- APC | c.2977A>T p.K993* | Nonsense Mutation (SNP) | VAF 92/210 reads (44%) | catalogued as CD160907, CM056294, COSV57326945, COSV57371737; called by muse, mutect2, varscan2
- AQP2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772051028, CM024087, COSV52229934; called by muse, mutect2, varscan2
- BRINP3 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1421033267, COSV66542098; called by muse, mutect2, varscan2
- CCDC27 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs370631959; called by muse, mutect2, varscan2
- CLASRP | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.09); catalogued as COSV55519545, COSV99674048; called by muse, mutect2, varscan2
- CNTFR | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs767106678, COSV63633139; called by muse, mutect2, varscan2
- CNTN6 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs144743086, COSV100611989; called by muse, mutect2, varscan2
- COMMD4 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as rs1051257703, COSV51191198; called by muse, mutect2, varscan2
- CSH2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs745741116; called by muse, mutect2, varscan2
- CXXC5 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1283965885, COSV56796094; called by muse, mutect2, varscan2
- EPB41L4A | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs200620569, COSV54863291; called by muse, mutect2, varscan2
- F13A1 | c.1001G>T p.R334I | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53568130; called by muse, mutect2
- FAM181A | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300954148, COSV50890758; called by muse, mutect2, varscan2
- FGD1 | c.2057C>A p.S686Y | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV64309720; called by muse, mutect2
- FRMPD2 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427226263, COSV59724074; called by muse, mutect2, varscan2
- GABRG1 | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369652618; called by muse, mutect2, varscan2
- GPD2 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs746974136, COSV60097302; called by muse, mutect2, varscan2
- GPER1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775750584, COSV52470756; called by muse, mutect2
- GPX2 | c.456del p.W152* | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | catalogued as rs773382437; called by mutect2, pindel, varscan2
- GUCY1A1 | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs372152908; called by muse, mutect2, varscan2
- IGHM | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.788); catalogued as rs782615938; called by muse, mutect2, varscan2
- INPPL1 | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99996698; called by muse, mutect2, varscan2
- ITIH2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs372514815; called by muse, mutect2, varscan2
- IVL | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV64217276; called by mutect2, varscan2
- LARS1 | c.2734C>T p.R912* (on ENST00000394434 / NM_020117.11; = p.R885* on NM_016460.3) | Nonsense Mutation (SNP) | VAF 57/189 reads (30%) | catalogued as rs199516658, COSV50972400; called by muse, mutect2, varscan2
- LRRC37A3 | c.4628C>T p.T1543M | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs780479466, COSV58534390; called by muse, mutect2, varscan2
- MAGEE1 | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63910158; called by muse, mutect2, varscan2
- NAA50 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV53787289; called by muse, mutect2, varscan2
- OR2A42 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs369404996; called by muse, mutect2, varscan2
- PCDH11X | c.1817C>T p.T606M | Missense Mutation (SNP) | VAF 90/250 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs771338985, COSV53506109; called by muse, mutect2, varscan2
- PCDH18 | c.546dup p.N183* | Frame Shift Ins (INS) | VAF 70/154 reads (45%) | catalogued as rs752780691; called by mutect2, varscan2
- PER3 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1279744616, COSV62705795; called by muse, mutect2, varscan2
- PRKCE | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1184220025, COSV60324134, COSV60330306; called by muse, mutect2, varscan2
- PRRC2B | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV61943374; called by muse, mutect2, varscan2
- QRICH1 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); catalogued as COSV62617729; called by muse, mutect2, varscan2
- RAB11FIP2 | c.385C>T p.R129* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as COSV62926203; called by muse, mutect2, varscan2
- REV3L | c.7082A>G p.Y2361C | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV62623723; called by muse, mutect2, varscan2
- SFXN4 | c.275G>C p.S92T | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.322); catalogued as COSV57461129; called by muse, mutect2, varscan2
- SGCE | c.256G>A p.V86I (on ENST00000647096; = p.V50I on NM_003919.3) | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs1562867795, COSV56020819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC8A1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1231443890, COSV60470187, COSV60474519; called by muse, mutect2, varscan2
- SMC1A | c.2132G>T p.R711L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs782176647, CM101868, COSV59129751, COSV59132016; called by muse, mutect2, varscan2
- ST3GAL1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | PolyPhen possibly damaging (0.851); catalogued as rs145826176; called by muse, mutect2, varscan2
- SYT17 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs775318995, COSV62548310; called by muse, mutect2, varscan2
- TCF7L2 | c.1463G>A p.R488H (on ENST00000355995 / NM_001367943.1; = p.R465H on NM_030756.5) | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as COSV53338022, COSV53349437; called by muse, mutect2, varscan2
- TET3 | c.4525C>T p.R1509* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs1314007418, COSV69645698; called by muse, mutect2, varscan2
- TNRC6B | c.3943C>T p.R1315* (on ENST00000454349 / NM_001162501.2; = p.R1205* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as COSV57308330; called by muse, mutect2, varscan2
- TRPS1 | c.2288G>C p.S763T (on ENST00000220888 / NM_001330599.2; = p.S776T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/546 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV55263222; called by muse, mutect2, varscan2
- USP34 | c.4289A>G p.K1430R | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs768912118, COSV68407021; called by muse, mutect2, varscan2
- ZBED4 | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.37); catalogued as rs756748204, COSV53468362; called by muse, mutect2, varscan2
- ZNF28 | c.1424T>G p.V475G | Missense Mutation (SNP) | VAF 241/336 reads (72%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.5); catalogued as COSV60425596; called by muse, mutect2, varscan2
- ZNF578 | c.1508G>T p.R503I | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.19); catalogued as COSV69736025, COSV69737673; called by muse, mutect2, varscan2
- AGO4 | c.2170_2171del p.E724Kfs*16 | Frame Shift Del (DEL) | VAF 41/177 reads (23%) | called by mutect2, pindel, varscan2
- APC | c.4464_4470del p.L1488Ffs*17 | Frame Shift Del (DEL) | VAF 48/210 reads (23%) | called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.878-6_883del p.X293_splice (on ENST00000354667 / NM_031243.3; = p.X281_splice on NM_002137.4) | Splice Site (DEL) | VAF 54/140 reads (39%) | called by mutect2, pindel, varscan2
- PTPN20 | c.560dup p.N187Kfs*2 | Frame Shift Ins (INS) | VAF 35/91 reads (38%) | called by mutect2, varscan2
- UBN2 | c.1626dup p.L543Tfs*6 | Frame Shift Ins (INS) | VAF 41/135 reads (30%) | called by mutect2, pindel, varscan2
- ATG2B | c.5691A>G p.L1897= | Silent (SNP) | VAF 62/262 reads (24%) | catalogued as COSV55892198; called by muse, mutect2, varscan2
- CD2AP | c.576T>G p.P192= | Silent (SNP) | VAF 21/324 reads (6%) | catalogued as COSV100830670; called by muse, mutect2
- CD5L | c.12A>T p.L4= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV63823195; called by muse, mutect2, varscan2
- DNAH5 | c.13119C>A p.P4373= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV54253577; called by muse, mutect2, varscan2
- DOCK8 | c.2991C>T p.H997= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs190559109, COSV66624129; called by muse, mutect2, varscan2
- FRMPD3 | c.3804G>T p.R1268= | Silent (SNP) | VAF 57/125 reads (46%) | catalogued as COSV52197487; called by muse, mutect2, varscan2
- GABRG2 | c.1161C>T p.F387= (on ENST00000361925 / NM_001375343.1; = p.F347= on NM_000816.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as COSV62722808; called by muse, mutect2, varscan2
- GMPPB | c.741C>T p.G247= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV57540236; called by muse, mutect2, varscan2
- MYOM2 | c.2901G>C p.L967= | Silent (SNP) | VAF 31/125 reads (25%) | catalogued as rs557796981, COSV50778287; called by muse, mutect2, varscan2
- OR4C13 | c.252C>G p.L84= | Silent (SNP) | VAF 293/781 reads (38%) | catalogued as COSV73648945; called by muse, mutect2, varscan2
- PLEKHA5 | c.2781C>T p.I927= | Silent (SNP) | VAF 37/53 reads (70%) | catalogued as rs571301437, COSV54713048; called by muse, mutect2, varscan2
- SLFN11 | c.1032C>T p.T344= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as rs746027644, COSV100390732, COSV57700661; called by muse, mutect2, varscan2
- SPATA5 | c.339G>A p.L113= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV56784906; called by muse, mutect2, varscan2
- TIMP3 | c.522C>T p.Y174= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV56666838; called by muse, mutect2, varscan2
- ZNF415 | c.525T>A p.V175= | Silent (SNP) | VAF 7/196 reads (4%) | catalogued as COSV99702096; called by muse, mutect2
- MIR889 | n.22G>A | RNA (SNP) | VAF 4/11 reads (36%) | catalogued as rs373212727; called by muse, mutect2, varscan2
- NXF5 | n.763C>G | RNA (SNP) | VAF 68/598 reads (11%) | catalogued as COSV53793628; called by muse, mutect2, varscan2
- TNN | c.-107C>T | 5'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99513158; called by muse, mutect2, varscan2
- ZNF322P1 | n.11C>A | RNA (SNP) | VAF 139/547 reads (25%) | called by muse, mutect2, varscan2
